Somatic mutation profile of tumor specimen 0DU1X7 from CCDI case PBCGZG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Malignant tumor, spindle cell type; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 0.4 years (158 days).
Specimen 0DU1X7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07c4b088-f8e9-4760-b224-1f9b891e09a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU1W6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c280910-1208-4f80-bd5e-4b4a30200c02

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USP17L18 | c.1212del p.K404Nfs*31 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | catalogued as rs1560541801, COSV101543610; called by mutect2, pindel
- MAP2 | c.3126C>T p.V1042= | Silent (SNP) | VAF 199/1469 reads (14%) | catalogued as rs1483947664; called by muse, mutect2, varscan2
